Somatic mutation profile of tumor specimen C3N-02375-01 (aliquot CPT0146480010) from CPTAC case C3N-02375, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 59.9 years (21,871 days).
Specimen C3N-02375-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8224ade-c5e1-4d08-83b7-e9ee5a86af37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02375-71 (Blood Derived Normal), aliquot CPT0146510002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18520659-fef2-471e-a706-37757b9ab76d

The open-access MAF lists 279 somatic variants for this specimen: 182 protein-altering or splice-affecting, 60 silent, 37 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 143, Silent 60, Intron 17, Nonsense Mutation 16, Splice Site 9, Frame Shift Del 8, 5'Flank 5, 5'UTR 5, RNA 5, 3'UTR 4, Splice Region 3, In Frame Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.101G>A p.R34Q | Missense Mutation (SNP) | VAF 103/162 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960096, COSV67960161, COSV67961129; called by muse, mutect2, varscan2
- TP53 | c.254del p.P85Lfs*38 | Frame Shift Del (DEL) | VAF 121/252 reads (48%) | catalogued as rs1064793279, COSV53087170; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AHNAK2 | c.5438A>T p.D1813V | Missense Mutation (SNP) | VAF 310/1283 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.355); catalogued as COSV60907928; called by muse, mutect2, varscan2
- AMBRA1 | c.97G>T p.V33L | Missense Mutation (SNP) | VAF 111/263 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.97); catalogued as rs1565283271; called by muse, mutect2, varscan2
- CACNG7 | c.128C>A p.P43Q | Missense Mutation (SNP) | VAF 111/370 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as rs769846106, COSV55815845; called by muse, mutect2, varscan2
- CARD11 | c.3398G>T p.R1133L | Missense Mutation (SNP) | VAF 122/401 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV67799266, COSV67799679, COSV67803766; called by muse, mutect2, varscan2
- CCP110 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs1184835116; called by muse, mutect2, varscan2
- CCT8L2 | c.1271C>T p.S424F | Missense Mutation (SNP) | VAF 106/312 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.222); catalogued as rs752606207; called by muse, mutect2, varscan2
- CFAP69 | c.2794G>A p.V932M | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as rs765228770; called by muse, mutect2
- CFHR5 | c.1172C>A p.P391Q | Missense Mutation (SNP) | VAF 63/186 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV56825837; called by muse, mutect2, varscan2
- COL11A1 | c.3526C>G p.Q1176E | Missense Mutation (SNP) | VAF 101/181 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV62194092; called by muse, mutect2, varscan2
- CPSF2 | c.1140+1G>A p.X380_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as rs1029661122; called by muse, mutect2, varscan2
- DLC1 | c.305C>A p.A102D | Missense Mutation (SNP) | VAF 47/142 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.905); catalogued as COSV52306666; called by muse, mutect2, varscan2
- DOCK8 | c.4109G>A p.R1370H | Missense Mutation (SNP) | VAF 60/378 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.608); catalogued as rs753480025, COSV66618594; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EHBP1L1 | c.2765C>T p.S922L | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1341670553; called by muse, mutect2, varscan2
- ELP5 | c.640-1G>T p.X214_splice | Splice Site (SNP) | VAF 66/119 reads (55%) | catalogued as rs1161569290; called by muse, mutect2, varscan2
- EPG5 | c.3438G>T p.L1146F | Missense Mutation (SNP) | VAF 30/167 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV56344241; called by muse, mutect2, varscan2
- ESPNL | c.2693G>A p.R898H | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs780851502; called by muse, mutect2, varscan2
- GALNT17 | c.512C>G p.S171C | Missense Mutation (SNP) | VAF 48/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100351772, COSV61165138; called by muse, mutect2, varscan2
- JAKMIP2 | c.2183A>G p.Q728R | Missense Mutation (SNP) | VAF 109/199 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.888); catalogued as rs776444502; called by muse, mutect2, varscan2
- KCNH7 | c.3172C>T p.Q1058* | Nonsense Mutation (SNP) | VAF 5/44 reads (11%) | catalogued as COSV59808383; called by muse, mutect2
- KIF13A | c.4802C>T p.S1601F | Missense Mutation (SNP) | VAF 79/133 reads (59%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs757196364; called by muse, mutect2, varscan2
- LAMA1 | c.3659G>A p.R1220Q | Missense Mutation (SNP) | VAF 106/404 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); catalogued as rs367987988; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LINGO2 | c.1702C>T p.R568* | Nonsense Mutation (SNP) | VAF 107/185 reads (58%) | catalogued as COSV58065987; called by muse, mutect2, varscan2
- LRATD2 | c.236A>T p.H79L | Missense Mutation (SNP) | VAF 174/475 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV59230072; called by muse, mutect2, varscan2
- MAGI2 | c.2599G>T p.E867* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV62683805, COSV62684832; called by muse, mutect2, varscan2
- MYO1A | c.1795C>T p.Q599* | Nonsense Mutation (SNP) | VAF 285/702 reads (41%) | catalogued as rs143570906; called by muse, mutect2, varscan2
- NPAS4 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 59/216 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.588); catalogued as rs138829720; called by muse, mutect2, varscan2
- NYAP2 | c.1030del p.V344Cfs*29 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | catalogued as COSV99798242; called by mutect2, varscan2
- OR11H12 | c.318C>A p.N106K | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs1329556548, COSV101612499; called by mutect2, varscan2
- OR5A2 | c.942C>A p.H314Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV57390607; called by muse, mutect2
- PCDHAC1 | c.2337C>G p.D779E | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.15); PolyPhen benign (0.09); catalogued as COSV53841616; called by muse, mutect2, varscan2
- PIWIL3 | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 16/184 reads (9%) | catalogued as rs1176218314, COSV100177729; called by muse, mutect2
- POU4F2 | c.563T>A p.L188Q | Missense Mutation (SNP) | VAF 170/321 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.762); catalogued as rs892063849; called by muse, varscan2
- RYR2 | c.10747A>T p.K3583* | Nonsense Mutation (SNP) | VAF 37/98 reads (38%) | catalogued as COSV63689449; called by muse, mutect2, varscan2
- SEMA5A | c.983C>T p.A328V | Missense Mutation (SNP) | VAF 42/412 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.036); catalogued as rs375422150; called by muse, mutect2
- SLC6A15 | c.1579T>A p.Y527N | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57026529; called by muse, mutect2, varscan2
- SPTB | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 62/249 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779720812, COSV67635814; called by muse, mutect2, varscan2
- STXBP2 | c.167C>T p.T56I | Missense Mutation (SNP) | VAF 256/636 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138007892; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEDC1 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 112/506 reads (22%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.947); catalogued as rs781932897; called by muse, mutect2, varscan2
- TLN2 | c.1558G>A p.D520N | Missense Mutation (SNP) | VAF 92/272 reads (34%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.821); catalogued as rs1158778982, COSV100168271; called by muse, mutect2, varscan2
- TRIM49 | c.250C>A p.L84I | Missense Mutation (SNP) | VAF 41/250 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.078); catalogued as rs570663427; called by muse, mutect2, varscan2
- TTN | c.19643T>C p.V6548A (on ENST00000591111; = p.V5621A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | PolyPhen benign (0.015); catalogued as COSV60195441; called by muse, mutect2, varscan2
- TTYH3 | c.158G>A p.C53Y | Missense Mutation (SNP) | VAF 96/280 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1311789746; called by muse, mutect2, varscan2
- USH2A | c.9437T>C p.L3146P | Missense Mutation (SNP) | VAF 62/160 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100228420; called by muse, mutect2, varscan2
- USP24 | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 22/38 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.321); catalogued as rs1400996163; called by muse, mutect2, varscan2
- USPL1 | c.1870A>G p.T624A | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs776340758; called by muse, mutect2, varscan2
- VWC2L | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.553); catalogued as rs937017932; called by muse, mutect2, varscan2
- ZDHHC6 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV61132695; called by muse, mutect2, varscan2
- ZNF208 | c.3816G>T p.K1272N | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV68103774; called by muse, mutect2, varscan2
- ZNF333 | c.589G>A p.A197T | Missense Mutation (SNP) | VAF 41/235 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs140185448; called by muse, mutect2, varscan2
- ZNF716 | c.79C>A p.L27M | Missense Mutation (SNP) | VAF 32/134 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV70782444; called by muse, mutect2, varscan2
- ZNF721 | c.1363C>T p.H455Y (on ENST00000338977; = p.H467Y on NM_133474.4) | Missense Mutation (SNP) | VAF 40/72 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV59096345; called by muse, mutect2, varscan2
- AC026316.4 | c.488A>C p.Q163P | Missense Mutation (SNP) | VAF 29/266 reads (11%) | PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ADAM22 | c.1355T>G p.I452S | Missense Mutation (SNP) | VAF 74/243 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ADD3 | c.2056A>T p.K686* (on ENST00000356080 / NM_001320591.2; = p.K654* on NM_001121.4) | Nonsense Mutation (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- AFF2 | c.1139A>C p.H380P | Missense Mutation (SNP) | VAF 14/178 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.068); called by muse, mutect2
- AGBL1 | c.1826T>C p.I609T | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AKAP3 | c.2176G>A p.A726T | Missense Mutation (SNP) | VAF 79/207 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ALDH2 | c.771del p.V258Wfs*12 | Frame Shift Del (DEL) | VAF 97/345 reads (28%) | called by mutect2, pindel, varscan2
- ALPI | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 83/264 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- ARHGAP22 | c.1603A>T p.S535C | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ARID1A | c.759_762del p.S254Pfs*108 | Frame Shift Del (DEL) | VAF 23/57 reads (40%) | called by pindel, varscan2
- ARMC9 | c.1538A>G p.H513R | Missense Mutation (SNP) | VAF 45/246 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.477); called by muse, mutect2, varscan2
- ARMCX5 | c.691G>T p.V231F | Missense Mutation (SNP) | VAF 85/130 reads (65%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ATP2C2 | c.131A>G p.E44G | Missense Mutation (SNP) | VAF 53/204 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- BOD1L1 | c.2102A>T p.K701M | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- CAMSAP3 | c.1988G>A p.G663D | Missense Mutation (SNP) | VAF 47/127 reads (37%) | SIFT tolerated (0.63); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC39 | c.2054T>C p.I685T | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2
- CCP110 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- CEP295NL | c.243A>C p.K81N | Missense Mutation (SNP) | VAF 100/310 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- CEP63 | c.1765A>G p.I589V | Missense Mutation (SNP) | VAF 154/286 reads (54%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CFAP44 | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 112/225 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- CNTN6 | c.1130A>T p.N377I | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CP | c.2356C>A p.Q786K | Missense Mutation (SNP) | VAF 134/245 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- CPNE1 | c.527A>T p.Y176F (on ENST00000352393; = p.Y181F on NM_003915.5) | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- CREBBP | c.5414C>G p.T1805S | Missense Mutation (SNP) | VAF 47/196 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CROT | c.1594A>G p.K532E | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CTAGE1 | c.1192C>A p.L398M | Missense Mutation (SNP) | VAF 62/214 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CUL3 | c.1708-2A>T p.X570_splice | Splice Site (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- DAPK1 | c.1825-1G>A p.X609_splice | Splice Site (SNP) | VAF 131/334 reads (39%) | called by muse, mutect2, varscan2
- DIAPH2 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DISC1 | c.1952G>T p.R651I | Missense Mutation (SNP) | VAF 15/230 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); called by muse, mutect2
- DNAH5 | c.2984-1G>A p.X995_splice | Splice Site (SNP) | VAF 105/317 reads (33%) | called by muse, mutect2, varscan2
- E2F2 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 8/228 reads (4%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- ECM1 | c.1471C>T p.P491S | Missense Mutation (SNP) | VAF 148/432 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ELMOD3 | c.130-2A>C p.X44_splice | Splice Site (SNP) | VAF 100/306 reads (33%) | called by muse, mutect2, varscan2
- EPG5 | c.3439G>T p.E1147* | Nonsense Mutation (SNP) | VAF 29/167 reads (17%) | called by muse, mutect2, varscan2
- ERRFI1 | c.202+3A>T | Splice Region (SNP) | VAF 70/106 reads (66%) | called by muse, mutect2, varscan2
- EYA4 | c.1582A>G p.T528A (on ENST00000531901 / NM_001301013.1; = p.T522A on NM_004100.5) | Missense Mutation (SNP) | VAF 18/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- GABRG3 | c.1271G>A p.C424Y | Missense Mutation (SNP) | VAF 108/303 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GREB1 | c.165C>A p.S55R | Missense Mutation (SNP) | VAF 36/157 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GRPR | c.654C>A p.F218L | Missense Mutation (SNP) | VAF 108/155 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- HAUS5 | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 64/385 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- HAUS5 | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 65/387 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HDAC4 | c.366G>T p.K122N | Missense Mutation (SNP) | VAF 33/212 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- HEATR9 | c.731C>G p.S244C | Missense Mutation (SNP) | VAF 126/364 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- HGF | c.1835G>A p.C612Y | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HS3ST3A1 | c.624C>A p.D208E | Missense Mutation (SNP) | VAF 48/97 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- INSYN2B | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 38/60 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- IQCG | c.8A>T p.E3V | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- ITGB4 | c.3808A>T p.M1270L | Missense Mutation (SNP) | VAF 323/789 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- JPH4 | c.285_286delinsA p.S95Rfs*154 | Frame Shift Del (DEL) | VAF 62/324 reads (19%) | called by pindel, varscan2*
- KIF21A | c.3608G>T p.G1203V (on ENST00000361418 / NM_001378440.1; = p.G1190V on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 112/344 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIF2B | c.1921T>A p.S641T | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KLHL1 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.893); called by muse, mutect2, varscan2
- LGI2 | c.749G>A p.S250N | Missense Mutation (SNP) | VAF 29/280 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LILRA2 | c.951A>T p.T317= | Splice Region (SNP) | VAF 23/180 reads (13%) | called by muse, mutect2, varscan2
- LRGUK | c.1721del p.G574Dfs*6 | Frame Shift Del (DEL) | VAF 40/151 reads (26%) | called by mutect2, pindel, varscan2
- LRP2 | c.13625C>T p.T4542I | Missense Mutation (SNP) | VAF 69/158 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- LRRTM4 | c.200C>G p.S67* | Nonsense Mutation (SNP) | VAF 91/235 reads (39%) | called by muse, mutect2, varscan2
- MAGEB6 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 158/224 reads (71%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- MCF2 | c.503C>A p.T168N | Missense Mutation (SNP) | VAF 69/101 reads (68%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MMP2 | c.1267C>T p.P423S | Missense Mutation (SNP) | VAF 71/291 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- MON2 | c.1962A>C p.Q654H | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MOV10L1 | c.2588C>G p.T863R | Missense Mutation (SNP) | VAF 93/309 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPS5 | c.1274T>G p.L425W | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); called by muse, mutect2
- MUC16 | c.35341G>T p.E11781* | Nonsense Mutation (SNP) | VAF 49/197 reads (25%) | called by muse, mutect2, varscan2
- NDNF | c.807G>C p.Q269H | Missense Mutation (SNP) | VAF 73/130 reads (56%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- NGLY1 | c.57G>T p.E19D | Missense Mutation (SNP) | VAF 198/312 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- NWD1 | c.1547G>T p.S516I | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- OCA2 | c.1801G>T p.D601Y | Missense Mutation (SNP) | VAF 70/245 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR13D1 | c.925T>C p.S309P | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- OR52D1 | c.607C>G p.L203V | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5D18 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 9/23 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- OR5M1 | c.725C>T p.A242V | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- PCDHB12 | c.1563C>G p.Y521* | Nonsense Mutation (SNP) | VAF 330/612 reads (54%) | called by muse, mutect2, varscan2
- PDE2A | c.1857_1865del p.I619_S621del | In Frame Del (DEL) | VAF 46/297 reads (15%) | called by mutect2, pindel, varscan2
- PDE3A | c.2213A>T p.Y738F | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PIK3CG | c.755T>C p.M252T | Missense Mutation (SNP) | VAF 70/219 reads (32%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PJVK | c.436C>G p.R146G | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); called by muse, mutect2, varscan2
- PLXNA4 | c.1506C>A p.L502= | Splice Region (SNP) | VAF 63/178 reads (35%) | called by muse, mutect2, varscan2
- PPP1R3A | c.652T>G p.F218V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPDC1 | c.997G>A p.D333N (on ENST00000375360 / NM_177995.3; = p.D385N on NM_152422.4) | Missense Mutation (SNP) | VAF 70/238 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- PTPRB | c.193G>T p.A65S | Missense Mutation (SNP) | VAF 140/484 reads (29%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PURG | c.1003G>A p.G335S | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RAX | c.679G>T p.G227C | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- RBM20 | c.685T>C p.Y229H | Missense Mutation (SNP) | VAF 143/337 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- REST | c.337A>G p.S113G | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- REST | c.1354A>G p.K452E | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); called by muse, mutect2, varscan2
- RETREG1 | c.1235T>A p.L412Q (on ENST00000306320 / NM_001034850.2; = p.L271Q on NM_019000.4) | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- RNF180 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF44 | c.107+2T>C p.X36_splice | Splice Site (SNP) | VAF 69/187 reads (37%) | called by muse, mutect2, varscan2
- RRP12 | c.2293G>A p.D765N | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SAAL1 | c.1402C>T p.P468S | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SALL3 | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 104/516 reads (20%) | called by muse, mutect2, varscan2
- SEC16B | c.2038A>T p.K680* | Nonsense Mutation (SNP) | VAF 58/156 reads (37%) | called by muse, mutect2, varscan2
- SGMS1 | c.1113C>A p.Y371* | Nonsense Mutation (SNP) | VAF 11/197 reads (6%) | called by muse, mutect2
- SHOX2 | c.527G>A p.R176Q (on ENST00000441443 / NM_006884.3; = p.R200Q on NM_003030.4) | Missense Mutation (SNP) | VAF 230/749 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SIPA1L3 | c.804G>T p.K268N | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- SIPA1L3 | c.805G>T p.D269Y | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SLC32A1 | c.1513G>A p.V505M | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- SMG7 | c.1757A>C p.K586T | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SOHLH2 | c.578T>A p.L193* | Nonsense Mutation (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- SPAM1 | c.917T>A p.I306K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.215); called by muse, mutect2
- TBR1 | c.1274A>T p.Y425F | Missense Mutation (SNP) | VAF 107/219 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- TDRD5 | c.641-1G>T p.X214_splice | Splice Site (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- TEAD4 | c.1130T>G p.L377R | Missense Mutation (SNP) | VAF 112/304 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TERT | c.2032G>T p.A678S | Missense Mutation (SNP) | VAF 68/287 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- TIAM2 | c.895C>A p.L299I | Missense Mutation (SNP) | VAF 43/298 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TMEM132D | c.1243G>T p.V415L | Missense Mutation (SNP) | VAF 20/294 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.015); called by muse, mutect2
- TNFRSF11A | c.916G>T p.G306C | Missense Mutation (SNP) | VAF 97/336 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- TNFRSF11A | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 92/322 reads (29%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); called by mutect2, varscan2
- TNKS | c.3206G>T p.G1069V | Missense Mutation (SNP) | VAF 42/121 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TREML2 | c.271A>T p.T91S | Missense Mutation (SNP) | VAF 28/229 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- TRIM50 | c.84G>T p.M28I | Missense Mutation (SNP) | VAF 180/517 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); called by mutect2, varscan2
- TRIM64B | c.237G>T p.Q79H | Missense Mutation (SNP) | VAF 208/1060 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.049); called by muse, varscan2
- TTN | c.38339A>G p.E12780G (on ENST00000591111; = p.E5356G on NM_003319.4) | Missense Mutation (SNP) | VAF 59/326 reads (18%) | PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- UNC13A | c.4913T>A p.L1638Q | Missense Mutation (SNP) | VAF 153/595 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- USH2A | c.6427C>A p.P2143T | Missense Mutation (SNP) | VAF 122/328 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- VANGL2 | c.1430T>A p.V477D | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2
- WAPL | c.1104_1113del p.C369Pfs*100 | Frame Shift Del (DEL) | VAF 46/148 reads (31%) | called by mutect2, pindel, varscan2
- WAPL | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 47/109 reads (43%) | called by muse, mutect2, varscan2
- WDR25 | c.381G>T p.M127I | Missense Mutation (SNP) | VAF 146/262 reads (56%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZCCHC17 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); called by mutect2, varscan2
- ZIC2 | c.415T>A p.F139I | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ZNF230 | c.181_183del p.E61del | In Frame Del (DEL) | VAF 26/72 reads (36%) | called by pindel, varscan2
- ZNF585B | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 289/496 reads (58%) | SIFT tolerated (0.07); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- ZNF607 | c.716G>T p.R239L | Missense Mutation (SNP) | VAF 96/176 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- ZNF674 | c.654A>T p.Q218H | Missense Mutation (SNP) | VAF 67/138 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZNF695 | c.167-1G>T p.X56_splice | Splice Site (SNP) | VAF 106/221 reads (48%) | called by muse, mutect2, varscan2
- ZNF750 | c.787_793del p.G263Rfs*101 | Frame Shift Del (DEL) | VAF 78/241 reads (32%) | called by pindel, varscan2*
- ABCB5 | c.1779G>C p.V593= (on ENST00000404938 / NM_001163941.2; = p.V148= on NM_178559.6) | Silent (SNP) | VAF 59/177 reads (33%) | called by muse, mutect2, varscan2
- AKAP12 | c.5262A>G p.E1754= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as rs561845205; called by muse, mutect2, varscan2
- ANK2 | c.9753T>A p.A3251= | Silent (SNP) | VAF 38/57 reads (67%) | called by muse, mutect2, varscan2
- ARF3 | c.435G>A p.L145= | Silent (SNP) | VAF 123/350 reads (35%) | called by muse, mutect2, varscan2
- CDH18 | c.1989C>T p.G663= | Silent (SNP) | VAF 58/249 reads (23%) | catalogued as rs367628466; called by muse, mutect2, varscan2
- CEBPA | c.453G>T p.G151= | Silent (SNP) | VAF 96/137 reads (70%) | called by muse, varscan2
- CHST8 | c.906C>T p.T302= | Silent (SNP) | VAF 68/555 reads (12%) | called by muse, mutect2, varscan2
- COG6 | c.138G>A p.R46= | Silent (SNP) | VAF 90/360 reads (25%) | called by muse, mutect2
- COL20A1 | c.1311C>T p.A437= | Silent (SNP) | VAF 130/232 reads (56%) | called by muse, mutect2, varscan2
- CYP24A1 | c.199C>T p.L67= | Silent (SNP) | VAF 192/326 reads (59%) | called by muse, mutect2, varscan2
- DNAH3 | c.9805C>T p.L3269= | Silent (SNP) | VAF 101/234 reads (43%) | called by muse, mutect2, varscan2
- EPPK1 | c.4614G>A p.L1538= | Silent (SNP) | VAF 155/437 reads (35%) | catalogued as rs373681462, COSV73260819; called by muse, mutect2, varscan2
- EYS | c.1494T>C p.D498= | Silent (SNP) | VAF 125/301 reads (42%) | called by muse, mutect2, varscan2
- GABRA5 | c.342C>A p.P114= | Silent (SNP) | VAF 98/410 reads (24%) | called by muse, mutect2, varscan2
- GPD2 | c.312A>C p.S104= | Silent (SNP) | VAF 40/229 reads (17%) | called by muse, mutect2, varscan2
- GPR179 | c.2505C>T p.P835= (on ENST00000621958; = p.P834= on NM_001004334.4) | Silent (SNP) | VAF 129/582 reads (22%) | catalogued as rs774635072; called by muse, mutect2, varscan2
- HMCN1 | c.6006A>G p.L2002= | Silent (SNP) | VAF 69/225 reads (31%) | called by muse, mutect2, varscan2
- HS3ST3B1 | c.699G>A p.R233= | Silent (SNP) | VAF 159/344 reads (46%) | called by muse, mutect2, varscan2
- HSF2BP | c.153G>T p.L51= | Silent (SNP) | VAF 87/112 reads (78%) | called by muse, mutect2, varscan2
- IKBKG | c.903G>T p.L301= | Silent (SNP) | VAF 102/292 reads (35%) | called by muse, varscan2
- IL22RA2 | c.696A>G p.T232= | Silent (SNP) | VAF 43/230 reads (19%) | called by muse, mutect2, varscan2
- IRF2BP1 | c.1698C>T p.G566= | Silent (SNP) | VAF 10/88 reads (11%) | catalogued as rs1338941781; called by muse, mutect2, varscan2
- IRX2 | c.1026G>A p.Q342= | Silent (SNP) | VAF 125/304 reads (41%) | called by muse, mutect2, varscan2
- LAMA2 | c.831G>C p.S277= | Silent (SNP) | VAF 26/198 reads (13%) | catalogued as rs765960304, COSV70337899; called by muse, mutect2, varscan2
- LTBP1 | c.2802C>A p.T934= (on ENST00000404816 / NM_206943.4; = p.T608= on NM_000627.4) | Silent (SNP) | VAF 77/315 reads (24%) | catalogued as COSV100616579; called by muse, mutect2, varscan2
- MKRN3 | c.492C>T p.S164= | Silent (SNP) | VAF 121/341 reads (35%) | called by muse, mutect2, varscan2
- MUC2 | c.2160T>C p.C720= | Silent (SNP) | VAF 212/471 reads (45%) | called by muse, mutect2, varscan2
- MYCBP2 | c.582G>T p.V194= (on ENST00000357337; = p.V232= on NM_015057.5) | Silent (SNP) | VAF 32/118 reads (27%) | called by muse, mutect2, varscan2
- MYO15B | c.8310C>A p.G2770= | Silent (SNP) | VAF 162/486 reads (33%) | called by muse, mutect2, varscan2
- MYPN | c.3456C>A p.T1152= | Silent (SNP) | VAF 171/649 reads (26%) | catalogued as COSV100590308; called by muse, mutect2, varscan2
- NCOA1 | c.3342G>A p.R1114= | Silent (SNP) | VAF 44/146 reads (30%) | catalogued as rs1388495246; called by muse, mutect2, varscan2
- NCOR2 | c.3969C>G p.S1323= | Silent (SNP) | VAF 117/217 reads (54%) | called by muse, mutect2, varscan2
- NHS | c.2364A>G p.P788= | Silent (SNP) | VAF 109/148 reads (74%) | called by muse, mutect2, varscan2
- NPY1R | c.718A>C p.R240= | Silent (SNP) | VAF 17/28 reads (61%) | called by muse, mutect2, varscan2
- OR14K1 | c.456C>T p.A152= | Silent (SNP) | VAF 70/200 reads (35%) | catalogued as COSV51720458; called by muse, mutect2, varscan2
- OR2A5 | c.471G>T p.L157= | Silent (SNP) | VAF 153/388 reads (39%) | catalogued as COSV101278659; called by muse, mutect2, varscan2
- OR2M2 | c.495C>A p.S165= | Silent (SNP) | VAF 72/238 reads (30%) | catalogued as rs1232336249, COSV100677294; called by muse, mutect2, varscan2
- OR2T27 | c.30C>G p.A10= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs148569814; called by muse, mutect2, varscan2
- PACS1 | c.2526C>T p.D842= | Silent (SNP) | VAF 189/475 reads (40%) | catalogued as rs756607682, COSV57699509; called by muse, mutect2, varscan2
- PCDH15 | c.105T>C p.A35= | Silent (SNP) | VAF 48/145 reads (33%) | called by muse, mutect2, varscan2
- PIEZO1 | c.774C>T p.G258= | Silent (SNP) | VAF 220/580 reads (38%) | called by muse, mutect2, varscan2
- POTEE | c.687C>G p.G229= | Silent (SNP) | VAF 4/24 reads (17%) | called by mutect2, varscan2
- PRPH | c.1173C>A p.I391= | Silent (SNP) | VAF 160/406 reads (39%) | called by muse, mutect2, varscan2
- RAB37 | c.153C>T p.D51= | Silent (SNP) | VAF 119/442 reads (27%) | catalogued as rs530556816, COSV61194837; called by muse, mutect2, varscan2
- RELN | c.7635C>A p.A2545= | Silent (SNP) | VAF 161/475 reads (34%) | catalogued as COSV59000477; called by muse, mutect2, varscan2
- REV1 | c.3105G>A p.A1035= | Silent (SNP) | VAF 137/442 reads (31%) | catalogued as rs183307465, COSV51490620; called by muse, mutect2, varscan2
- RNF146 | c.675A>T p.V225= (on ENST00000368314 / NM_001242850.2; = p.V224= on NM_030963.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 89/243 reads (37%) | called by muse, mutect2, varscan2
- RTN1 | c.1479C>T p.S493= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as rs979941221, COSV50736111; called by muse, mutect2, varscan2
- SKAP2 | c.606T>G p.A202= | Silent (SNP) | VAF 28/78 reads (36%) | called by muse, mutect2, varscan2
- SLC22A11 | c.684G>A p.A228= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs76833677, COSV57251998; called by muse, mutect2, varscan2
- SMARCA5 | c.2166A>G p.K722= | Silent (SNP) | VAF 12/14 reads (86%) | called by muse, mutect2, varscan2
- SPIC | c.519C>G p.L173= | Silent (SNP) | VAF 84/258 reads (33%) | catalogued as rs751233935; called by muse, mutect2, varscan2
- SULT1C3 | c.168G>A p.K56= | Silent (SNP) | VAF 5/17 reads (29%) | called by muse, mutect2, varscan2
- TAFA5 | c.285G>A p.Q95= (on ENST00000402357 / NM_001082967.3; = p.Q88= on NM_015381.7) | Silent (SNP) | VAF 57/139 reads (41%) | called by muse, mutect2, varscan2
- TOB1 | c.699C>T p.G233= | Silent (SNP) | VAF 12/276 reads (4%) | called by muse, mutect2
- TOGARAM1 | c.3225A>G p.Q1075= | Silent (SNP) | VAF 14/45 reads (31%) | called by muse, mutect2, varscan2
- TOPBP1 | c.3120C>T p.A1040= | Silent (SNP) | VAF 53/265 reads (20%) | catalogued as COSV53439362; called by muse, mutect2, varscan2
- TRPS1 | c.561A>G p.P187= (on ENST00000220888 / NM_001330599.2; = p.P200= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 80/228 reads (35%) | called by muse, mutect2, varscan2
- UBFD1 | c.837C>A p.P279= | Silent (SNP) | VAF 19/184 reads (10%) | called by muse, mutect2, varscan2
- VKORC1 | c.54G>C p.T18= | Silent (SNP) | VAF 120/722 reads (17%) | catalogued as rs771891906, COSV56231760, COSV56232230; called by muse, mutect2, varscan2
- ABCB8 | c.1268+564G>A | Intron (SNP) | VAF 91/351 reads (26%) | catalogued as rs780849361; called by muse, mutect2, varscan2
- AC103993.1 | n.70T>A | RNA (SNP) | VAF 50/154 reads (32%) | called by muse, mutect2, varscan2
- AGAP1 | c.164-38793G>T | Intron (SNP) | VAF 33/200 reads (17%) | catalogued as COSV100365749; called by muse, mutect2, varscan2
- AIP | c.787+33C>T | Intron (SNP) | VAF 119/291 reads (41%) | catalogued as rs760788018; called by muse, mutect2, varscan2
- BBS9 | c.2299-15G>A | Intron (SNP) | VAF 61/182 reads (34%) | called by muse, mutect2, varscan2
- BPNT1 | c.*947C>G | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- CALML6 | chr1:1915245 G>C | 5'Flank (SNP) | VAF 85/127 reads (67%) | called by muse, mutect2, varscan2
- CCL27 | c.70+28G>T | Intron (SNP) | VAF 36/632 reads (6%) | called by muse, mutect2
- CHRNB1 | c.244-44C>T | Intron (SNP) | VAF 92/145 reads (63%) | called by muse, mutect2, varscan2
- CLN3 | c.303-36C>T | Intron (SNP) | VAF 81/205 reads (40%) | catalogued as rs777827050, COSV61106615; called by muse, mutect2, varscan2
- DZIP3 | c.1963-81G>T | Intron (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- EFHC1 | c.*2023T>C | 3'UTR (SNP) | VAF 71/436 reads (16%) | catalogued as rs886061638; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ESCO1 | c.1954-628A>T | Intron (SNP) | VAF 37/82 reads (45%) | called by muse, mutect2, varscan2
- ITGA7 | chr12:55712202 T>A | 5'Flank (SNP) | VAF 63/141 reads (45%) | called by muse, mutect2
- KCNAB1 | c.276-129587G>T | Intron (SNP) | VAF 279/1301 reads (21%) | catalogued as rs552884415, COSV56753149; called by muse, mutect2, varscan2
- KIF5C | c.292-2233G>A | Intron (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- LINC01164 | n.891G>C | RNA (SNP) | VAF 116/464 reads (25%) | called by muse, mutect2, varscan2
- LINC02740 | n.251C>T | RNA (SNP) | VAF 74/232 reads (32%) | catalogued as rs1409179472; called by muse, mutect2, varscan2
- LRRC55 | c.*40A>T | 3'UTR (SNP) | VAF 77/308 reads (25%) | called by muse, mutect2, varscan2
- MIA3 | c.-14G>T | 5'UTR (SNP) | VAF 137/385 reads (36%) | called by muse, mutect2, varscan2
- MIRLET7BHG | n.309-3678C>T | Intron (SNP) | VAF 229/580 reads (39%) | catalogued as rs760719406; called by muse, mutect2, varscan2
- MS4A6A | c.-227T>A | 5'UTR (SNP) | VAF 22/86 reads (26%) | called by muse, mutect2, varscan2
- MTMR11 | c.-9G>T | 5'UTR (SNP) | VAF 16/569 reads (3%) | called by muse, mutect2
- NCR1 | c.-1G>T | 5'UTR (SNP) | VAF 172/425 reads (40%) | catalogued as rs368771137; called by muse, mutect2, varscan2
- OR52B1P | n.7G>T | RNA (SNP) | VAF 34/106 reads (32%) | called by muse, mutect2, varscan2
- PARP8 | c.2378-60G>T | Intron (SNP) | VAF 29/191 reads (15%) | catalogued as COSV55859349; called by muse, mutect2, varscan2
- PAX6 | c.141+20C>A | Intron (SNP) | VAF 31/84 reads (37%) | catalogued as CD166769; called by muse, mutect2, varscan2
- PPIG | c.-146C>G | 5'UTR (SNP) | VAF 10/214 reads (5%) | called by muse, mutect2
- RN7SL484P | chr15:99792252 A>G | 3'Flank (SNP) | VAF 26/514 reads (5%) | called by muse, mutect2
- SLC17A4 | c.1121-36C>A | Intron (SNP) | VAF 98/141 reads (70%) | called by muse, mutect2, varscan2
- SMPD4BP | n.1529G>T | RNA (SNP) | VAF 69/220 reads (31%) | called by muse, mutect2, varscan2
- TMEM121B | chr22:17122654 A>G | 5'Flank (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- TNFRSF14 | chr1:2556323 G>C | 5'Flank (SNP) | VAF 29/45 reads (64%) | called by muse, mutect2, varscan2
- UGT2A3 | c.864+1983A>G | Intron (SNP) | VAF 80/134 reads (60%) | called by muse, varscan2
- VNN3 | c.*36G>T | 3'UTR (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- WT1 | chr11:32437903 G>T | 5'Flank (SNP) | VAF 56/195 reads (29%) | catalogued as rs1349635606; called by muse, mutect2, varscan2
- ZNF606 | c.-52+360A>G | Intron (SNP) | VAF 53/192 reads (28%) | called by muse, mutect2, varscan2
